CCDI case PBBLES — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/205db27d-3cd8-477b-a239-e4b07f6ddcb3

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.7 years (1,721 days).

Biospecimens (3 samples)
- Sample 0DBD08: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBD09: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DBD0A: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
